Surgical pathology report (de-identified scan), TCGA case TCGA-S8-A6BV, project TCGA-ESCA (Esophageal Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-S8-A6BV-01A (Primary Tumor).

[page 1 of 4]
Operative Procedure:

Ivor Lewis esophagectomy/pancreatectomy

Specimen Received:

- A: Stomach margin (-) (FS)
- B: left pancreas + spleen
- C: body of pancreas margin (-) (FS)
- D: Esophageal margin (FS)
- E: Esophagus

Final Pathologic Diagnosis:

- A. Stomach, excision of margin:
Negative for malignancy.
Frozen section diagnosis confirmed.
- B. Pancreas, distal, pancreatectomy:
Benign pancreatic cyst, 0.5 cm.
Patchy low grade pancreatic intraepithelial neoplasia.
Twelve benign lymph nodes (0/12).
- Spleen, splenectomy:
Negative for malignancy.
- C. Pancreas, excision of margin:
Negative for malignancy.
Frozen section diagnosis confirmed.
- D. Esophagus, excision of margin:
Negative for malignancy.
Frozen section diagnosis confirmed.

E. Esophagus, esophagogastrectomy

Specimen: Esophagus, proximal stomach

Procedure: Esophagogastrectomy

Tumor site: Esophagogastric junction (EGJ)

Relationship of tumor to esophagogastric junction: Tumor midpoint lies in the distal esophagus

Tumor size: 4.5 cm

Histologic type: Adenocarcinoma

Histologic grade: Moderately differentiated

Microscopic tumor extension: Tumor invades the muscularis propria into the periesophageal soft tissue

Margins:

Proximal margin: Uninvolved by invasive carcinoma

Distal margin: Uninvolved by invasive carcinoma

Circumferential margin: Uninvolved by invasive carcinoma

ICD-O-3

Adenocarcinoma NOS
8140/3

Site C&F Distal third of
esophagus 85.5
path Esophagogastric
junction C16.0
JW 5/24/13

Dis-/Synchronous Primary H. J. Les		

[page 2 of 4]
Distance of invasive carcinoma from closest margin is 0.1 cm

Specify margin: Circumferential margin

Treatment effect: None

Lymph-vascular invasion: Not seen

Perineural invasion: Not seen

Pathologic staging (pTNM):

Primary tumor:T3

Regional lymph nodes: pN1

Number examined: 16

Number involved:2

Distant metastasis: None known

Additional pathologic findings:Intestinal metaplasia (Barrett esophagus) with high-grade dysplasia

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Intraoperative Consult Diagnosis:

FSA: Stomach margin:

Negative.

F/S TAT: 20 mins.

FSC: Body of pancreas margin:

Negative for tumor.

F/S TAT: 15 mins.

FSD: Esophageal margin:

Negative.

F/S TAT: 20 mins.

Gross Description:

A. Received without fixative labeled "stomach margin"

are two irregular partial gastric wall excisions, 4.7 x 1.8 x 1.0 cm and 9.5 x 3.0 x 2.5 cm. There is minimal adherent fat. Multiple staple lines are present. The mucosa is tan with the normal folds. A representative section is submitted for frozen section microscopy, now in cassette A1. Additional representative sections are submitted in cassette A2.

B. Received in formalin, labeled "left pancreas and

spleen" is a 4.9 x 3.3 x 1.8 cm distal pancreas with attached 136 gram, 9.5 x 8.0 x 4.3 cm spleen and a moderate amount of attached fat. Located 2.9 cm from the resection margin is a 0.5 x 0.4 x 0.4 cm smooth walled, uniloculated pancreatic cyst, which comes to within 0.2 cm from the inked external surface. This cyst appears to involve a side branch of the main pancreatic duct. The remaining pancreas is tan and lobulated. No discrete solid lesions are identified. The pancreatic duct appears probe patent, averaging less than 0.1 cm.

[page 3 of 4]
The capsule of the spleen is purple-pink, smooth, glistening and intact. Sectioning reveals a red-pink, soft, homogeneous parenchyma with prominent white pulp. No discrete lesions are present. Multiple tan-pink, rubbery lymph nodes are identified in the attached fat, up to 0.5 cm.

Representative sections are submitted as follows:

- B1 cyst in its entirety to include inked external surface;
- B2-6 pancreas submitted sequentially from proximal to distal (not entirely submitted);
- B7 spleen;
- B8-9 multiple whole possible lymph nodes.

C. Received without fixative labeled "body of pancreas margin" is a 2.3 x 1.8 x 0.2 cm tan, irregular soft tissue, submitted in toto for frozen section microscopy, now in cassette C.

D. Received without fixative labeled "esophageal margin" is a 4.5 x 0.7 x 0.4 cm irregular soft tissue, partially surfaced by a tan, wrinkled mucosa. A representative section is submitted for frozen section microscopy, now in cassette D1.

Representative sections of the remaining tissue are submitted in cassette D2.

E. Received in formalin, labeled "esophagus" is a 5.5 cm segment of distal esophagus with attached up to 5 cm of proximal stomach with a moderate amount of attached fat. Involving the proximal stomach, 0.6 cm from the distal margin and 5 cm from the proximal margin is a 4.5 x 2.2 cm tan, irregular well delineated, focally ulcerated raised mass. This mass on sectioning is tan, firm, heterogeneous, focally cystic with a total thickness of 2.0 cm, extending to the muscularis propria with possible involvement of the subjacent fat, coming within less than 0.1 cm from the inked deep soft tissue margin. The uninvolved esophageal mucosa is tan-pink and wrinkled. The uninvolved gastric mucosa is tan with the normal folds. The gastroesophageal junction is well delineated. Multiple tan-pink, rubbery to firm lymph nodes are identified in the attached fat up to 2 cm.

Representative sections are submitted as follows:

- E1-2 mass to inked deep soft tissue margin;
- E3 mass with adjacent uninvolved esophageal mucosa;
- E4 mass with adjacent uninvolved gastric mucosa;
- E5 gastroesophageal junction, uninvolved;
- E6-7 multiple whole lymph nodes;
- E8 one whole lymph node trisected;
- E9 one whole lymph node bisected;
- E10 one whole lymph node bisected;
- E11 one whole lymph node bisected;
- E12 representative section from one lymph node;
- E13 representative sections from one lymph node.

Microscopic Description:

[page 4 of 4]
The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken: DOB: (Age:) Gender: M

Source: NCI Genomic Data Commons file 5f949c81-4a49-4ce8-8f3e-fea4c4ffe630 (TCGA-S8-A6BV.15E8D407-DE20-4D26-BB59-0F4823C8688D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).